Somatic mutation profile of tumor specimen TCGA-17-Z016-01A (aliquot TCGA-17-Z016-01A-01W-0746-08) from TCGA case TCGA-17-Z016, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d89cef34-ac28-4a20-ba80-13a831b1a1e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z016-11A (Solid Tissue Normal), aliquot TCGA-17-Z016-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fb68ca8-029f-4d74-802b-879fddbd17a3

The open-access MAF lists 327 somatic variants for this specimen: 251 protein-altering or splice-affecting, 66 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 213, Silent 66, Nonsense Mutation 18, Frame Shift Del 7, Intron 5, Frame Shift Ins 4, Splice Region 3, Splice Site 3, RNA 2, Nonstop Mutation 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.650C>A p.T217K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as rs149308698; called by muse, mutect2, varscan2
- AK5 | c.1439C>A p.P480Q (on ENST00000354567 / NM_174858.3; = p.P454Q on NM_012093.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1438579932; called by muse, mutect2, varscan2
- ANO1 | c.2575G>C p.V859L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.531); catalogued as rs371604155; called by muse, mutect2, varscan2
- ARHGAP44 | c.1445G>T p.R482L | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.23); PolyPhen benign (0.103); catalogued as rs762077923; called by muse, mutect2, varscan2
- ARSI | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1351384764; called by muse, mutect2, varscan2
- ASPHD1 | c.988G>A p.G330S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs780682176; called by muse, mutect2, varscan2
- ATM | c.3257G>T p.R1086L | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs769857066, COSV53752225, COSV53785859; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1B | c.2551C>G p.Q851E | Missense Mutation (SNP) | VAF 86/117 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV100290068; called by muse, mutect2, varscan2
- BDP1 | c.6085G>C p.D2029H | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV62433467; called by muse, mutect2, varscan2
- CD36 | c.716G>T p.W239L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1393025883; called by muse, mutect2
- CDH11 | c.524-1G>T p.X175_splice | Splice Site (SNP) | VAF 42/106 reads (40%) | catalogued as COSV51761852, COSV51766795; called by muse, mutect2, varscan2
- CEP192 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1170739580, COSV100380565; called by muse, mutect2, varscan2
- CEP290 | c.4682G>C p.R1561P | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs371157150; called by muse, mutect2, varscan2
- CERS6 | c.770A>T p.Q257L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs376524029; called by muse, mutect2
- CNTN5 | c.1635C>A p.D545E | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54299115, COSV99682841; called by muse, mutect2, varscan2
- COL11A1 | c.1099G>C p.G367R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.152); catalogued as COSV62184750; called by muse, mutect2, varscan2
- CSMD1 | c.10081G>T p.G3361W (on ENST00000520002; = p.G3360W on NM_033225.6) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358051627; called by muse, mutect2, varscan2
- CSMD1 | c.8011G>A p.G2671S (on ENST00000520002; = p.G2670S on NM_033225.6) | Missense Mutation (SNP) | VAF 164/373 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1009864779, COSV59342449; called by muse, mutect2, varscan2
- CSMD1 | c.3895T>A p.Y1299N (on ENST00000520002; = p.Y1298N on NM_033225.6) | Missense Mutation (SNP) | VAF 124/282 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV59358343; called by muse, mutect2, varscan2
- CTNND2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs778030487, COSV58867380; called by muse, mutect2, varscan2
- DCAF8L1 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV71595446; called by muse, mutect2, varscan2
- DDX59 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.03); catalogued as rs190172329; called by muse, mutect2, varscan2
- DENND2A | c.1123+2T>A p.X375_splice | Splice Site (SNP) | VAF 32/81 reads (40%) | catalogued as rs1480690093; called by muse, mutect2, varscan2
- DGKI | c.482A>G p.K161R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1313530013; called by muse, mutect2, varscan2
- DLAT | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs1555181946; called by muse, mutect2, varscan2
- DLG4 | c.1318G>A p.D440N (on ENST00000399506 / NM_001321075.3; = p.D483N on NM_001365.4) | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs1457576861, COSV100263807; called by muse, mutect2, varscan2
- DLG5 | c.5057G>T p.R1686L | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1161241786, COSV64947785; called by muse, mutect2, varscan2
- DMD | c.10697G>T p.R3566L | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58897842; called by muse, mutect2, varscan2
- EIF1AD | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1199607901; called by muse, mutect2, varscan2
- EPHA5 | c.3020G>A p.R1007Q | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs145811811, COSV56640997; called by muse, mutect2, varscan2
- FOXL2 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1199674242; called by muse, mutect2
- GABRA5 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs754287701; called by muse, mutect2
- GRID1 | c.910C>A p.L304M | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV100024735, COSV60024216, COSV60030402; called by muse, mutect2, varscan2
- GRM7 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as rs1264339637; called by muse, mutect2, varscan2
- GTF3C2 | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as rs1182395533; called by muse, mutect2, varscan2
- HGF | c.1379C>A p.P460H | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55947960, COSV99738689; called by muse, mutect2, varscan2
- HIVEP3 | c.3571C>A p.L1191I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1330461706; called by muse, mutect2, varscan2
- HRNR | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0.112); catalogued as rs773921910; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs753434721; called by muse, mutect2, varscan2
- IL5RA | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.829); catalogued as rs201368484; called by muse, mutect2, varscan2
- INPP5B | c.1116G>T p.Q372H (on ENST00000373023; = p.Q292H on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1201924671; called by muse, mutect2, varscan2
- JADE1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as rs753338723; called by muse, mutect2, varscan2
- JAK3 | c.1477A>T p.S493C | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV71686313, COSV71686956; called by muse, mutect2, varscan2
- KCNN2 | c.1642G>T p.D548Y (on ENST00000264773; = p.D760Y on NM_021614.4) | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV53289829, COSV53296894; called by muse, mutect2, varscan2
- KCTD19 | c.1480T>G p.W494G | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1302130014; called by muse, mutect2, varscan2
- KCTD3 | c.2285G>T p.G762V | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.122); catalogued as rs770382387, COSV52064468; called by muse, mutect2, varscan2
- KRTAP23-1 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 31/74 reads (42%) | PolyPhen probably damaging (0.922); catalogued as COSV61935493; called by muse, mutect2, varscan2
- LILRA4 | c.397del p.V133* | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as rs1213856644, COSV52492629; called by mutect2, varscan2
- LRP1B | c.11413T>A p.C3805S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1383579315; called by muse, mutect2, varscan2
- MLIP | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV51433074; called by muse, mutect2, varscan2
- MYBL2 | c.1198G>T p.G400C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.936); catalogued as rs1468448974, COSV53831113; called by muse, mutect2, varscan2
- NELFCD | c.757A>G p.M253V (on ENST00000602795; = p.M235V on NM_198976.4) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1238483488; called by muse, mutect2, varscan2
- NINL | c.2964G>T p.R988S | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV99624802; called by muse, mutect2, varscan2
- NLRP3 | c.2575T>C p.Y859H | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as CM116411; called by muse, mutect2, varscan2
- NPRL2 | c.323A>C p.Y108S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV51602518; called by muse, mutect2, varscan2
- NSD1 | c.3554G>T p.C1185F | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100728581; called by muse, mutect2, varscan2
- NTNG2 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV62368817; called by muse, mutect2, varscan2
- NTRK2 | c.1629G>C p.E543D (on ENST00000323115 / NM_001369534.1; = p.E559D on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52868573; called by muse, mutect2, varscan2
- ODF1 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV53432294; called by mutect2, varscan2
- OOEP | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV64859413, COSV64859578; called by muse, mutect2, varscan2
- OR10P1 | c.783C>G p.I261M | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as COSV59007591; called by muse, mutect2, varscan2
- OR10Q1 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757852188; called by muse, mutect2, varscan2
- OR2M2 | c.216G>T p.M72I | Missense Mutation (SNP) | VAF 115/381 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs1387615752; called by muse, mutect2, varscan2
- OR56A4 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775373604; called by muse, mutect2, varscan2
- PAPOLA | c.1106A>T p.Q369L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.267); catalogued as COSV53481809; called by muse, mutect2, varscan2
- PAX1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.325); catalogued as COSV68271704; called by muse, mutect2, varscan2
- PCDHA7 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65342685; called by muse, mutect2, varscan2
- PCDHB5 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | catalogued as COSV50665407; called by muse, mutect2, varscan2
- PDE11A | c.1173G>T p.E391D | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.769); catalogued as COSV99615987; called by muse, mutect2, varscan2
- PHIP | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV99244692; called by muse, mutect2, varscan2
- PIK3R5 | c.1783C>A p.L595M | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.5); catalogued as COSV99353652; called by muse, mutect2, varscan2
- PLA2G2F | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV64279835, COSV64279863; called by muse, mutect2, varscan2
- PLCD4 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs548113968, COSV68744476; called by muse, mutect2, varscan2
- PROP1 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 94/182 reads (52%) | catalogued as COSV57645533; called by muse, mutect2, varscan2
- PTGER4 | c.809T>A p.M270K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1321153825; called by muse, mutect2, varscan2
- PXDNL | c.1998G>T p.E666D | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1427592222, COSV100684602; called by muse, mutect2, varscan2
- RABEPK | c.1088A>G p.Y363C | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1445031787; called by muse, mutect2, varscan2
- RANBP3L | c.371G>T p.R124I | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99683951; called by muse, mutect2, varscan2
- RNF17 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs1311798139; called by muse, varscan2
- ROBO1 | c.991G>C p.V331L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as COSV71395995; called by muse, mutect2, varscan2
- RTL3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 17/17 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.508); catalogued as COSV58185984; called by muse, mutect2, varscan2
- SCRIB | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1263273458; called by muse, mutect2
- SGIP1 | c.63C>A p.D21E | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs149425441; called by muse, mutect2, varscan2
- SLC17A9 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1215803801; called by muse, mutect2, varscan2
- SLC27A1 | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs763436997; called by muse, mutect2, varscan2
- SLC38A9 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs141328492; called by muse, mutect2, varscan2
- SLC49A4 | c.1391G>T p.R464M | Missense Mutation (SNP) | VAF 124/342 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53747726; called by muse, mutect2, varscan2
- SLIT2 | c.2113G>T p.V705L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.399); catalogued as COSV56566983; called by muse, mutect2, varscan2
- SPATA31D1 | c.1685C>A p.P562H | Missense Mutation (SNP) | VAF 108/255 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as COSV61196536; called by muse, mutect2, varscan2
- SPOCK3 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100692282, COSV62737054; called by muse, mutect2, varscan2
- STAB2 | c.3335A>G p.D1112G | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483775924; called by muse, mutect2, varscan2
- TBC1D32 | c.3058G>T p.G1020C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167937267; called by muse, mutect2, varscan2
- TEX15 | c.6906C>A p.N2302K (on ENST00000256246; = p.N2685K on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1213467525; called by muse, mutect2, varscan2
- TGM7 | c.1618G>T p.G540C | Missense Mutation (SNP) | VAF 97/166 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs774865695, COSV71772884; called by muse, mutect2, varscan2
- TRIM15 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1233618547; called by muse, mutect2, varscan2
- TRPA1 | c.878C>A p.S293* | Nonsense Mutation (SNP) | VAF 37/89 reads (42%) | catalogued as COSV100085577; called by muse, mutect2, varscan2
- TTN | c.46225C>A p.P15409T (on ENST00000591111; = p.P7985T on NM_003319.4) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | PolyPhen possibly damaging (0.856); catalogued as COSV59861566; called by muse, mutect2, varscan2
- UGT1A8 | c.364dup p.S122Ffs*8 | Frame Shift Ins (INS) | VAF 26/114 reads (23%) | catalogued as rs762306873; called by mutect2, varscan2
- UNC13C | c.2816A>G p.N939S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs774501089; called by muse, mutect2, varscan2
- XIRP2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as rs372476244; called by muse, mutect2, varscan2
- ZEB2 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as CD147452; called by muse, mutect2, varscan2
- ZFPM2 | c.2021G>A p.S674N | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1400566117, COSV65872518; called by muse, mutect2, varscan2
- ZNF536 | c.2533C>A p.L845I | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.491); catalogued as rs370323894, COSV62821993; called by muse, varscan2
- ZNF620 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1477553627; called by muse, mutect2, varscan2
- ZNF8 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.467); catalogued as COSV99544698; called by muse, mutect2, varscan2
- ZNF804B | c.3469A>T p.K1157* | Nonsense Mutation (SNP) | VAF 42/95 reads (44%) | catalogued as COSV60836941; called by muse, mutect2, varscan2
- ZUP1 | c.1225G>T p.G409W | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754412333; called by muse, mutect2, varscan2
- ABCC1 | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM10 | c.1916G>A p.C639Y | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM29 | c.687del p.N230Ifs*2 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.2857T>A p.C953S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY7 | c.2143del p.L715Cfs*23 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- ADRA1B | c.671G>T p.C224F | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- AIP | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, varscan2
- AMY1B | c.885G>T p.W295C | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ANK1 | c.2751C>A p.F917L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK1 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- APOB | c.5456T>A p.L1819Q | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APPL1 | c.1695G>T p.T565= | Splice Region (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- ASTN2 | c.2165T>A p.L722Q (on ENST00000313400 / NM_001365069.1; = p.L671Q on NM_014010.5) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP1B1 | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BIN2 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- BIRC6 | c.9593C>T p.S3198F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BLMH | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD9 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- C14orf28 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD207 | c.170T>A p.V57D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2
- CDH18 | c.2167G>A p.A723T | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- CDH9 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDNF | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CECR2 | c.1975C>A p.L659M (on ENST00000342247 / NM_001290047.2; = p.L476M on NM_001290046.1) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP152 | c.3230G>A p.C1077Y | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHMP2B | c.275T>A p.M92K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- CHRM2 | c.273G>T p.L91F | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- CNKSR2 | c.1708C>A p.R570S | Missense Mutation (SNP) | VAF 105/120 reads (88%) | SIFT deleterious (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CNTNAP4 | c.2567T>A p.V856E | Missense Mutation (SNP) | VAF 147/429 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL17A1 | c.1262C>G p.T421S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPA3 | c.278T>G p.I93S | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPEB1 | c.1294G>T p.V432F (on ENST00000617958; = p.V367F on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSDE1 | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD2 | c.6367T>A p.C2123S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSTF3 | c.302G>T p.W101L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTNND2 | c.2933C>G p.A978G | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- DAB1 | c.8C>G p.T3S | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- DCAF7 | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DLEC1 | c.197T>A p.L66H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- DNASE2B | c.713T>A p.L238H | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DOCK2 | c.861C>G p.D287E | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DOCK4 | c.4285A>G p.K1429E | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DPP10 | c.1765A>T p.I589F | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DSC3 | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- DYNC2H1 | c.6588dup p.G2197Wfs*36 | Frame Shift Ins (INS) | VAF 34/91 reads (37%) | called by mutect2, pindel, varscan2
- EGFLAM | c.3014C>A p.A1005D (on ENST00000354891 / NM_001205301.2; = p.A997D on NM_152403.4) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ENPEP | c.2312G>T p.W771L | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EOMES | c.1601G>T p.S534I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- EXOC2 | c.2439G>A p.V813= | Splice Region (SNP) | VAF 60/154 reads (39%) | called by muse, mutect2
- EXOC6 | c.928A>T p.R310* | Nonsense Mutation (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- FAM133A | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FBN2 | c.8147del p.G2716Afs*79 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | called by mutect2, pindel
- FBN2 | c.5159C>T p.P1720L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FRYL | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- GRIK2 | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- HECW1 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HS3ST5 | c.118A>T p.I40F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2
- IFI35 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNGR2 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- IL20RB | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 54/126 reads (43%) | called by muse, mutect2, varscan2
- IRGC | c.884T>A p.I295N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- KCNC2 | c.421T>A p.W141R | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KIF26B | c.3341_3342del p.A1114Vfs*2 | Frame Shift Del (DEL) | VAF 22/45 reads (49%) | called by mutect2, pindel, varscan2
- KLRC2 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 83/104 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- KRT16 | c.639del p.Q214Rfs*17 | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | called by mutect2, pindel, varscan2
- KRTAP4-4 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- LAMA2 | c.7044T>A p.Y2348* | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- LAMB4 | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMC1 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- LAMC2 | c.2314G>T p.A772S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- LONP2 | c.1498G>T p.A500S | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRFN5 | c.395_406del p.N132_L135del | In Frame Del (DEL) | VAF 21/55 reads (38%) | called by mutect2, varscan2
- LRFN5 | c.2133G>T p.Q711H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC66 | c.1215G>T p.W405C | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRRIQ1 | c.2375G>T p.W792L | Missense Mutation (SNP) | VAF 141/292 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRN2 | c.1080C>A p.N360K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- MALT1 | c.1670A>T p.K557M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MARCHF11 | c.588T>G p.H196Q | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MCOLN3 | c.1124T>C p.I375T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEIS2 | c.775G>T p.V259L (on ENST00000561208 / NM_170675.5; = p.V246L on NM_002399.3) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MGST3 | c.253A>T p.I85L | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MROH2B | c.3270A>C p.L1090F | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MRPL9 | c.802T>A p.*268Kext*23 | Nonstop Mutation (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- MTARC2 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- MTMR7 | c.263G>T p.R88I | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, varscan2
- MUC16 | c.27997dup p.I9333Nfs*20 | Frame Shift Ins (INS) | VAF 62/100 reads (62%) | called by mutect2, pindel, varscan2
- NAV3 | c.3179C>A p.T1060N | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2
- NEBL | c.1153G>T p.G385* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- NMNAT2 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NPAP1 | c.1213G>T p.V405L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- NPL | c.394G>C p.A132P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NRXN3 | c.2699A>G p.K900R (on ENST00000335750 / NM_001330195.2; = p.K527R on NM_004796.6) | Missense Mutation (SNP) | VAF 95/159 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR2M4 | c.616A>T p.M206L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- OVOL2 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PCDH15 | c.1897G>T p.A633S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDHB11 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB9 | c.2038C>A p.Q680K | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PCDHGA5 | c.308_309del p.V103Gfs*4 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | called by pindel, varscan2
- PCSK6 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCSK6 | c.576G>T p.R192S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PDE3A | c.878G>C p.S293T | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PIGR | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.2109G>T p.R703S | Missense Mutation (SNP) | VAF 54/79 reads (68%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- PMS1 | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLR2D | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PPFIA2 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- PRPF4B | c.548G>C p.R183P | Missense Mutation (SNP) | VAF 95/188 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PSORS1C2 | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 30/49 reads (61%) | called by muse, mutect2, varscan2
- RAB22A | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- RFT1 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- RNF38 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPS6KA5 | c.138A>G p.I46M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN11A | c.2980T>C p.C994R | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SCN3A | c.5072A>T p.N1691I | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SH3PXD2B | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- SLC8A1 | c.1160C>A p.A387E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- SLCO1B1 | c.441T>G p.I147M | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLITRK1 | c.803A>T p.D268V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SORCS1 | c.2866C>G p.Q956E | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SOX3 | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SPAG17 | c.5564C>A p.T1855K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- SPTA1 | c.3114G>T p.E1038D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- SRCAP | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2
- STIM1 | c.743T>C p.L248S | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STOX1 | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.198); called by muse, mutect2
- SYNE1 | c.7558T>A p.F2520I (on ENST00000367255 / NM_182961.4; = p.F2527I on NM_033071.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TAF4 | c.2372-5_2372del p.X791_splice | Splice Site (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- THSD7A | c.3663C>A p.H1221Q | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TLR4 | c.322A>G p.I108V (on ENST00000355622 / NM_138554.5; = p.I68V on NM_003266.4) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TMEM132B | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TMEM72 | c.781dup p.Q261Pfs*27 | Frame Shift Ins (INS) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- TMEM87A | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMX3 | c.122A>T p.D41V | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, varscan2
- TRAV8-6 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 74/372 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRHR | c.24A>T p.E8D | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRIM48 | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TRPM1 | c.2597C>A p.S866Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- UROC1 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- USP13 | c.2257A>T p.T753S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- VWC2L | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VXN | c.340C>T p.L114= | Splice Region (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- ZEB1 | c.2434C>A p.P812T | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF540 | c.904A>G p.K302E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- ZNF620 | c.1180T>C p.C394R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAMTS10 | c.1894C>A p.R632= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs571080944; called by muse, mutect2
- ADCY1 | c.2682G>T p.L894= | Silent (SNP) | VAF 66/204 reads (32%) | called by muse, mutect2, varscan2
- ADGRV1 | c.4437G>T p.L1479= | Silent (SNP) | VAF 67/156 reads (43%) | called by muse, mutect2, varscan2
- AFF1 | c.1362A>T p.P454= | Silent (SNP) | VAF 58/136 reads (43%) | called by muse, mutect2, varscan2
- ARGFX | c.648G>T p.S216= | Silent (SNP) | VAF 65/130 reads (50%) | called by muse, mutect2, varscan2
- BCORL1 | c.1632C>G p.V544= | Silent (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- BIRC6 | c.9594C>T p.S3198= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1193225271; called by muse, mutect2, varscan2
- BRINP3 | c.312C>A p.A104= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs761568488; called by muse, mutect2, varscan2
- CABIN1 | c.4140C>T p.A1380= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs778876850; called by muse, mutect2, varscan2
- CD207 | c.774A>T p.A258= | Silent (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- CHRNA6 | c.1002G>A p.T334= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as rs775611153, COSV52379814, COSV52381408; called by muse, mutect2, varscan2
- CRHBP | c.792C>T p.C264= | Silent (SNP) | VAF 10/194 reads (5%) | catalogued as COSV57189714; called by muse, mutect2
- FIGN | c.2001A>G p.S667= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs1321288119; called by muse, mutect2, varscan2
- FLRT2 | c.861A>G p.Q287= | Silent (SNP) | VAF 94/393 reads (24%) | called by muse, mutect2, varscan2
- GPR139 | c.150C>A p.I50= | Silent (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- HMCN1 | c.11688A>T p.P3896= | Silent (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.1275G>A p.G425= | Silent (SNP) | VAF 53/115 reads (46%) | catalogued as rs763132170; called by muse, mutect2, varscan2
- IGF2R | c.3993C>T p.F1331= | Silent (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- IGLL5 | c.621A>T p.T207= | Silent (SNP) | VAF 72/120 reads (60%) | called by muse, mutect2, varscan2
- INPP4A | c.2028G>T p.V676= (on ENST00000074304 / NM_001134224.1; = p.V637= on NM_001566.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/12 reads (75%) | called by muse, mutect2
- KALRN | c.5331G>T p.R1777= (on ENST00000360013 / NM_001024660.4; = p.R80= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- KLHL28 | c.1449G>T p.V483= | Silent (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- KLK7 | c.618G>T p.G206= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV58344499; called by muse, mutect2, varscan2
- LSAMP | c.247C>A p.R83= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as rs762856060, COSV100372271; called by muse, mutect2, varscan2
- METTL7A | c.423G>A p.V141= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs1364112264; called by muse, mutect2, varscan2
- MUC16 | c.8061C>A p.T2687= | Silent (SNP) | VAF 44/56 reads (79%) | catalogued as COSV67494430; called by muse, mutect2, varscan2
- NAV2 | c.4429C>T p.L1477= (on ENST00000396087 / NM_001244963.2; = p.L1454= on NM_145117.5) | Silent (SNP) | VAF 67/145 reads (46%) | called by muse, mutect2, varscan2
- NAV3 | c.3177G>A p.S1059= | Silent (SNP) | VAF 72/134 reads (54%) | catalogued as rs761458394; called by muse, mutect2
- NETO1 | c.1524C>T p.H508= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs144601570, COSV55007674; called by muse, mutect2, varscan2
- NMBR | c.231C>A p.V77= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2
- NPL | c.393G>T p.V131= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs1323715517; called by muse, varscan2
- NPY2R | c.168C>A p.A56= | Silent (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- NT5C1B | c.1737C>G p.P579= (on ENST00000359846 / NM_001199086.2; = p.P519= on NM_033253.4) | Silent (SNP) | VAF 40/73 reads (55%) | called by muse, mutect2, varscan2
- NUP205 | c.805C>T p.L269= | Silent (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- NUSAP1 | c.1071G>A p.V357= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- NUTM1 | c.2598C>A p.L866= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as rs984112727; called by muse, mutect2, varscan2
- OR13C8 | c.756T>C p.Y252= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs774943032; called by muse, mutect2, varscan2
- OR14C36 | c.636C>A p.I212= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs1052952394, COSV58600979; called by muse, mutect2
- OR4C46 | c.84G>T p.V28= | Silent (SNP) | VAF 71/145 reads (49%) | catalogued as rs1565363942; called by muse, mutect2, varscan2
- OR8J1 | c.810T>A p.T270= | Silent (SNP) | VAF 66/74 reads (89%) | catalogued as COSV57319385; called by muse, mutect2, varscan2
- OSGEP | c.9G>A p.A3= | Silent (SNP) | VAF 55/91 reads (60%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.81G>T p.G27= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as COSV65296686; called by muse, mutect2, varscan2
- POM121L12 | c.771C>A p.V257= | Silent (SNP) | VAF 69/111 reads (62%) | called by muse, mutect2, varscan2
- PPARGC1B | c.570G>T p.R190= | Silent (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- PSAPL1 | c.963G>A p.L321= | Silent (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- PTPN13 | c.4251C>T p.R1417= (on ENST00000411767 / NM_080683.3; = p.R1398= on NM_006264.3) | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs750876206, COSV57416977; called by muse, mutect2, varscan2
- REG3G | c.30G>A p.V10= | Silent (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- RFT1 | c.348C>T p.V116= | Silent (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- SGCD | c.60G>A p.Q20= (on ENST00000435422 / NM_001128209.2; = p.Q21= on NM_000337.5) | Silent (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
- SI | c.5229A>T p.V1743= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs547324596; called by muse, mutect2, varscan2
- SIGLEC6 | c.819C>A p.L273= | Silent (SNP) | VAF 26/35 reads (74%) | called by muse, mutect2, varscan2
- SLC30A10 | c.1191G>C p.L397= | Silent (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- SNCG | c.270C>T p.V90= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- SOX14 | c.342C>T p.A114= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as rs761782099; called by muse, mutect2, varscan2
- SPAG16 | c.1482C>A p.L494= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs755134894; called by muse, mutect2, varscan2
- SPATS1 | c.474C>T p.Y158= | Silent (SNP) | VAF 64/148 reads (43%) | catalogued as COSV55824332; called by muse, mutect2, varscan2
- SPEN | c.2910A>T p.A970= | Silent (SNP) | VAF 47/82 reads (57%) | called by muse, mutect2, varscan2
- STX11 | c.138A>T p.R46= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- TOGARAM2 | c.165C>T p.A55= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs774354386, COSV65421619; called by muse, mutect2, varscan2
- TRHDE | c.804G>T p.S268= | Silent (SNP) | VAF 43/84 reads (51%) | catalogued as COSV53868854; called by muse, mutect2, varscan2
- TSHZ1 | c.3069G>T p.L1023= (on ENST00000580243 / NM_001308210.2; = p.L978= on NM_005786.6) | Silent (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- USP29 | c.1377C>T p.H459= | Silent (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- USP35 | c.63G>T p.L21= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs1364300026; called by muse, mutect2
- VPS50 | c.2211A>G p.V737= | Silent (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- ZNF536 | c.2523C>A p.A841= | Silent (SNP) | VAF 28/62 reads (45%) | called by muse, varscan2
- ZNF586 | c.213G>A p.T71= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs1045289802, COSV66972552; called by muse, mutect2, varscan2
- AL590867.2 | n.86C>A | RNA (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- DPP6 | c.627+20860C>A | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- GOSR2 | chr17:46940572 C>T | 3'Flank (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- LAIR1 | c.-1del | 5'UTR (DEL) | VAF 8/36 reads (22%) | catalogued as COSV100479683; called by mutect2, pindel, varscan2
- NEK7 | c.198+3234A>T | Intron (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- OR5P3 | c.*2G>T | 3'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, varscan2
- PDE4DIP | c.637-7109A>G | Intron (SNP) | VAF 15/42 reads (36%) | catalogued as rs782661380; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1382A>T | RNA (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- TENM2 | c.503-120853del | Intron (DEL) | VAF 230/689 reads (33%) | catalogued as rs777087399, COSV72856494; called by mutect2, pindel, varscan2
- ZGRF1 | c.3127+19C>T | Intron (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
